Somatic mutation profile of tumor specimen TCGA-FR-A44A-06A (aliquot TCGA-FR-A44A-06A-11D-A24R-08) from TCGA case TCGA-FR-A44A, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 36.7 years (13,398 days).
Specimen TCGA-FR-A44A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc822d45-b366-4810-95f9-6f9116704244.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A44A-10A (Blood Derived Normal), aliquot TCGA-FR-A44A-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e58f5a94-b440-4fef-b5ba-30ab07b76eb2

The open-access MAF lists 364 somatic variants for this specimen: 225 protein-altering or splice-affecting, 129 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 204, Silent 129, Nonsense Mutation 15, Intron 6, RNA 2, Frame Shift Del 2, Splice Region 2, 3'Flank 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DSG2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs371146201; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACE | c.3568C>T p.P1190S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.022); catalogued as rs1295931503, COSV52006153; called by muse, mutect2, varscan2
- ACTG2 | c.983T>G p.I328S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.941); catalogued as COSV61828231; called by muse, mutect2, varscan2
- ACTN1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866604513, COSV51991134; called by muse, mutect2, varscan2
- ADAMTS20 | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 13/103 reads (13%) | catalogued as COSV67130722, COSV67135166; called by muse, mutect2
- ADGRL2 | c.1996G>A p.E666K (on ENST00000370717 / NM_001366005.1; = p.E653K on NM_012302.4) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV54665268; called by muse, mutect2, varscan2
- AHNAK | c.14422G>A p.D4808N | Missense Mutation (SNP) | VAF 75/333 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs545421649, COSV57212134, COSV57217881; called by muse, mutect2, varscan2
- AK9 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53421013; called by muse, varscan2
- ALAS1 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050289; called by muse, mutect2, varscan2
- AMOT | c.2464G>T p.G822W (on ENST00000371959 / NM_001113490.1; = p.G413W on NM_133265.3) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59063074; called by muse, mutect2, varscan2
- ANAPC1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61975828; called by muse, mutect2
- ANK3 | c.13063A>G p.K4355E (on ENST00000280772 / NM_001320874.2; = p.K979E on NM_001149.3) | Missense Mutation (SNP) | VAF 75/274 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV55056028; called by muse, mutect2, varscan2
- AP4M1 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV57996154; called by muse, mutect2, varscan2
- APBA2 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 104/285 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV68790762; called by muse, mutect2, varscan2
- ASAH2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV61484079; called by muse, mutect2, varscan2
- ATP2B2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs766306375, COSV59488988; called by muse, mutect2, varscan2
- BIN1 | c.755T>A p.F252Y (on ENST00000316724 / NM_001320642.1; = p.F221Y on NM_004305.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52118154; called by muse, mutect2, varscan2
- BRDT | c.1534T>C p.Y512H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV62864730; called by muse, mutect2, varscan2
- BRINP3 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs267598249, COSV66519090; called by muse, mutect2, varscan2
- C8A | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 31/148 reads (21%) | catalogued as COSV100776510, COSV63483769; called by muse, mutect2, varscan2
- C9orf131 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs917021325, COSV56610944; called by muse, mutect2, varscan2
- CA2 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53406600; called by muse, mutect2, varscan2
- CACHD1 | c.1927C>T p.H643Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.838); catalogued as COSV51550322; called by muse, varscan2
- CACNA1B | c.5477C>T p.S1826F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.212); catalogued as COSV53124370; called by muse, mutect2, varscan2
- CALCRL | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV66474682; called by muse, mutect2
- CALML3 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as rs1234491898, COSV59449329, COSV59450362; called by mutect2, varscan2
- CATSPERB | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs866205134, COSV56428671; called by muse, mutect2, varscan2
- CCBE1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs1453496165, COSV67949824; called by muse, mutect2, varscan2
- CD300LG | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.036); catalogued as rs767557360, COSV53222930; called by muse, mutect2, varscan2
- CEL | c.1343C>T p.P448L (on ENST00000673714; = p.P445L on NM_001807.6) | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.213); catalogued as COSV100672397; called by muse, mutect2, varscan2
- CHN1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55033203; called by muse, mutect2
- CHRNA3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs759225098, COSV58775073; called by muse, mutect2, varscan2
- CHSY1 | c.1988A>G p.Y663C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54252971; called by muse, mutect2
- CIITA | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as COSV60856742; called by muse, mutect2, varscan2
- CLPSL1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65814836; called by muse, mutect2, varscan2
- COCH | c.1124G>A p.G375E (on ENST00000216361 / NM_001347720.1; = p.G310E on NM_004086.3) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.944); catalogued as COSV53550747; called by muse, mutect2, varscan2
- COG1 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV55429495; called by muse, mutect2
- COL14A1 | c.4417C>T p.R1473* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV52853392, COSV99921067; called by muse, mutect2, varscan2
- COL27A1 | c.5220C>T p.V1740= | Splice Region (SNP) | VAF 40/256 reads (16%) | catalogued as rs886514953, COSV61925511; called by muse, mutect2, varscan2
- CRACDL | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67407874; called by muse, mutect2, varscan2
- CSMD1 | c.9971G>A p.W3324* (on ENST00000520002; = p.W3323* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as rs1296676391, COSV100154217, COSV59317299; called by muse, mutect2, varscan2
- CSMD2 | c.7975G>A p.G2659R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV53907663, COSV53907909; called by muse, mutect2, varscan2
- CX3CR1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.197); catalogued as COSV64193759, COSV64195189; called by muse, mutect2, varscan2
- CYP2S1 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs762923707, COSV59505916; called by muse, mutect2, varscan2
- CYP2S1 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV59505927; called by muse, mutect2, varscan2
- DCAF4L1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60787115; called by muse, mutect2
- DCTN1 | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs1233012587, COSV62620384; called by muse, mutect2, varscan2
- DHX29 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV52418120, COSV52419430; called by muse, mutect2, varscan2
- DMRTB1 | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs150761078; called by muse, mutect2, varscan2
- DNAH3 | c.6320C>T p.T2107I | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54519099; called by muse, mutect2, varscan2
- DNAH5 | c.11771C>T p.S3924L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV54221650; called by muse, mutect2, varscan2
- DNAH5 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 23/172 reads (13%) | catalogued as COSV54221661, COSV54250132; called by muse, mutect2, varscan2
- DNAH9 | c.5498C>G p.S1833C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV52347496; called by muse, mutect2, varscan2
- DNAH9 | c.6001G>A p.E2001K | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52347509; called by muse, mutect2, varscan2
- DNAH9 | c.11317G>A p.E3773K | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV52347519; called by muse, mutect2, varscan2
- DNM3 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62457191; called by muse, mutect2, varscan2
- DNMT3A | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99261694; called by muse, mutect2, varscan2
- DOP1B | c.5966T>C p.V1989A | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV67693182; called by muse, mutect2, varscan2
- DSG1 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.029); catalogued as COSV57135011; called by muse, mutect2, varscan2
- EEF2 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV58579299; called by muse, mutect2
- EEF2KMT | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV69863436, COSV69863533; called by muse, mutect2, varscan2
- FAM83B | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV60921665; called by muse, mutect2, varscan2
- FBXO15 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs146975565; called by muse, mutect2, varscan2
- FGD5 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53241938; called by muse, mutect2
- FGGY | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.36); catalogued as rs758298995, COSV58032243; called by muse, mutect2
- FOXN1 | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV56881657; called by muse, mutect2
- GAP43 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs755917237, COSV59343948, COSV59347496; called by muse, mutect2, varscan2
- GIMAP8 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV56231157; called by muse, mutect2, varscan2
- GLYATL2 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV54849840; called by muse, varscan2
- GMPR | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.979); catalogued as rs1341787041, COSV52473270; called by muse, mutect2, varscan2
- GPD2 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV60092439; called by muse, mutect2, varscan2
- GPRC5C | c.1178C>T p.P393L (on ENST00000652232; = p.P348L on NM_018653.4) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs147088573; called by muse, mutect2, varscan2
- GRIA2 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV52387410; called by muse, mutect2, varscan2
- GRIK3 | c.2450G>A p.G817E | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66139150; called by muse, mutect2, varscan2
- GRIN2A | c.3965G>A p.G1322E | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV58021494; called by muse, mutect2, varscan2
- GRM7 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284848935, COSV63141902; called by muse, mutect2, varscan2
- GUCY1A1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56651341; called by muse, mutect2, varscan2
- GUCY2F | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV54301351; called by muse, mutect2, varscan2
- HCN3 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV64233559, COSV64233898; called by muse, mutect2, varscan2
- HIPK2 | c.3198G>A p.M1066I | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV69208956; called by muse, mutect2, varscan2
- HIVEP1 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65100891; called by muse, mutect2, varscan2
- HLA-DPA1 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV70088846; called by muse, mutect2
- HPSE2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs767720704, COSV65188152, COSV65188189; called by muse, mutect2, varscan2
- HS3ST3A1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99404198; called by muse, mutect2, varscan2
- HYDIN | c.13787C>T p.T4596I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV101125034; called by muse, mutect2, varscan2
- HYDIN | c.10480C>T p.L3494F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66868199; called by muse, mutect2
- IGF2R | c.6424C>T p.P2142S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63482204; called by muse, mutect2, varscan2
- IL1RL1 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52115365; called by muse, mutect2, varscan2
- INTS6L | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 32/97 reads (33%) | catalogued as rs868954446, COSV66083779; called by muse, mutect2, varscan2
- JAM3 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54452390, COSV54458211; called by muse, mutect2
- KCNQ5 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV59658410; called by muse, mutect2
- KEL | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs61729041, CM973372, COSV62334383; called by muse, mutect2, varscan2
- KIAA1217 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV56816068; called by muse, mutect2, varscan2
- KLHL26 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV99963115; called by muse, mutect2, varscan2
- KLRB1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57589642; called by muse, mutect2, varscan2
- LAG3 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV52567311; called by muse, mutect2, varscan2
- LIFR | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs746053471, COSV54686247; called by muse, mutect2, varscan2
- LRFN2 | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.401); catalogued as rs1413582796, COSV57826925; called by muse, mutect2
- LTBP1 | c.4705G>A p.D1569N (on ENST00000404816 / NM_206943.4; = p.D1243N on NM_000627.4) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as COSV55378807; called by muse, mutect2, varscan2
- LTBP2 | c.4498G>A p.G1500S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426458768, COSV56207607; called by muse, mutect2, varscan2
- MCM3AP | c.4118C>T p.S1373F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1292471608, COSV52439220; called by muse, mutect2, varscan2
- MCM5 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV53346142; called by muse, mutect2, varscan2
- MCM6 | c.1844G>A p.R615K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51466118; called by muse, mutect2, varscan2
- ME1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs142401926; called by muse, mutect2, varscan2
- MGAM | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1233061883, COSV72073535; called by muse, mutect2, varscan2
- MROH2B | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1324722439, COSV68181657, COSV68183436; called by muse, mutect2, varscan2
- MTUS2 | c.4030C>G p.L1344V (on ENST00000612955 / NM_001366650.1; = p.L323V on NM_015233.6) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as COSV66421075; called by muse, mutect2, varscan2
- MUC4 | c.16156G>A p.G5386R (on ENST00000463781 / NM_018406.7; = p.G1150R on NM_004532.6) | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.289); catalogued as rs769504147, COSV57778525; called by muse, mutect2
- MYH1 | c.4450G>A p.E1484K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV56843045, COSV56843441; called by muse, mutect2, varscan2
- MYOC | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as CD085827, CM004565, COSV99231439; called by muse, mutect2, varscan2
- NAT2 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.81); catalogued as COSV54061345; called by muse, mutect2, varscan2
- NLRP14 | c.2746G>A p.G916R | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55066664; called by muse, mutect2, varscan2
- NOX4 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV54452295; called by muse, mutect2, varscan2
- OPLAH | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374435478; called by muse, mutect2
- OR2W3 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV64455951, COSV64456750; called by muse, mutect2
- OR4C15 | c.453G>A p.M151I (on ENST00000314644; = p.M97I on NM_001001920.2) | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as rs763726329, COSV58951556; called by muse, mutect2, varscan2
- OR51A4 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs867454021, COSV66749221; called by muse, mutect2, varscan2
- OR51E2 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1207448763, COSV67807399; called by muse, mutect2, varscan2
- OR52N2 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57676713; called by muse, varscan2
- OR5I1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV56885670; called by muse, mutect2, varscan2
- OR5P3 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs769727774, COSV60429228; called by muse, mutect2, varscan2
- OR6N1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV58648230; called by muse, mutect2, varscan2
- OR9A2 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317248278, COSV63306532; called by muse, mutect2
- OTUD7A | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.641); catalogued as COSV61038305; called by muse, mutect2, varscan2
- PAK6 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53045422; called by muse, mutect2, varscan2
- PBXIP1 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs770215901, COSV63776985; called by muse, mutect2, varscan2
- PCDHGA1 | c.1067T>A p.V356D | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV65296188; called by muse, mutect2, varscan2
- PCNT | c.9839G>C p.R3280T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64027564; called by muse, mutect2
- PCSK5 | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762281568, COSV70449275; called by muse, mutect2, varscan2
- PCSK9 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV53766757; called by muse, mutect2, varscan2
- PDCD11 | c.2766G>A p.L922= | Splice Region (SNP) | VAF 25/80 reads (31%) | catalogued as rs770553508, COSV63933832; called by muse, mutect2, varscan2
- PEAK1 | c.3173C>T p.P1058L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as COSV100432859; called by muse, mutect2, varscan2
- PEAK1 | c.3172C>T p.P1058S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs747542919, COSV100432860; called by muse, mutect2, varscan2
- PGAP4 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); catalogued as rs565590120, COSV66387600; called by muse, mutect2
- PGLYRP4 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs147105602, COSV62835747; called by muse, mutect2
- PIK3C2G | c.2197C>T p.P733S (on ENST00000676171; = p.P692S on NM_004570.5) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV56798959, COSV56803001; called by muse, mutect2, varscan2
- PIK3R6 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs773900454, COSV61002887; called by muse, mutect2, varscan2
- PLA2R1 | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs765928415, COSV51778096; called by muse, mutect2, varscan2
- PLAA | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 32/104 reads (31%) | catalogued as rs756356161, COSV68305447; called by muse, mutect2, varscan2
- PLAGL1 | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV52786552; called by muse, mutect2
- PLCB4 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV53800335; called by muse, mutect2, varscan2
- PPP4R3B | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs1318389101, COSV55404249; called by muse, varscan2
- PRAG1 | c.3824C>T p.A1275V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.098); catalogued as COSV58160392; called by muse, mutect2, varscan2
- PRAMEF10 | c.1260C>G p.D420E | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as COSV99338903; called by muse, mutect2, varscan2
- PREX2 | c.4669C>T p.R1557C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs752310428, COSV55749284; called by muse, mutect2, varscan2
- PRKCB | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV57777593; called by muse, mutect2, varscan2
- PRR35 | c.1619T>C p.I540T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1293905278, COSV50313297; called by muse, mutect2, varscan2
- PTBP1 | c.911T>G p.V304G (on ENST00000349038 / NM_031991.4; = p.V330G on NM_002819.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62459701; called by mutect2, varscan2
- PTGS1 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV56289853; called by muse, mutect2, varscan2
- RADIL | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as rs778563888, COSV68200533; called by muse, mutect2, varscan2
- RARB | c.1064T>A p.L355* (on ENST00000383772 / NM_001290216.2; = p.L348* on NM_000965.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV51971470; called by muse, mutect2, varscan2
- RGS7 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.408); catalogued as rs1228547642, COSV58539889; called by muse, mutect2, varscan2
- RHOF | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57363106, COSV57364041; called by muse, mutect2
- RIMBP2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs889328408, COSV55471105; called by muse, mutect2, varscan2
- ROS1 | c.5303C>T p.S1768L | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.739); catalogued as COSV63854659, COSV63857818; called by muse, mutect2, varscan2
- RPL22 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV52377696; called by muse, mutect2, varscan2
- RPN2 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | catalogued as COSV52905299; called by muse, mutect2, varscan2
- RPS6KA3 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV65388906; called by muse, mutect2, varscan2
- RSBN1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs757034435, COSV54732222; called by muse, mutect2, varscan2
- RSPO1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV62974151; called by muse, mutect2, varscan2
- SAMD3 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100148140, COSV60775512; called by muse, mutect2, varscan2
- SATB1 | c.1984T>G p.F662V | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58669164; called by muse, mutect2, varscan2
- SCN7A | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV69271091; called by muse, mutect2, varscan2
- SDK2 | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66185332; called by muse, mutect2, varscan2
- SERPINB2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55092265; called by muse, mutect2, varscan2
- SESN1 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs143075960; called by muse, mutect2, varscan2
- SIN3A | c.2871T>A p.D957E | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.039); catalogued as COSV64582742; called by muse, mutect2, varscan2
- SLC10A2 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV55358638; called by muse, mutect2, varscan2
- SLC17A8 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60123557; called by muse, mutect2
- SLCO1B3 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53936833; called by muse, mutect2, varscan2
- SLCO6A1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as COSV65809232; called by muse, mutect2, varscan2
- SLITRK4 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100567192, COSV62023524; called by muse, mutect2, varscan2
- SLITRK6 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68389209, COSV68391037; called by muse, mutect2, varscan2
- SOST | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs745735992, COSV57012530; called by muse, mutect2, varscan2
- SRP14 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV51115548; called by muse, mutect2, varscan2
- SRPX2 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV65933526; called by muse, varscan2
- SSBP3 | c.713A>G p.N238S (on ENST00000371320 / NM_145716.4; = p.N218S on NM_018070.5) | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.19); catalogued as COSV58886327; called by muse, mutect2, varscan2
- STAC2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV61064903; called by muse, mutect2, varscan2
- STEAP3 | c.1084T>G p.S362A | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.846); catalogued as COSV100713269; called by muse, mutect2, varscan2
- SUCLG2 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56204980; called by muse, mutect2, varscan2
- SYT2 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.295); catalogued as COSV66141915; called by muse, mutect2, varscan2
- SYTL2 | c.2350C>T p.P784S (on ENST00000528231 / NM_001162951.2; = p.P760S on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs1403164799, COSV60358677; called by muse, mutect2
- TBATA | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54718918; called by muse, mutect2, varscan2
- TBC1D19 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as COSV53516425; called by muse, mutect2
- TBXT | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 48/195 reads (25%) | catalogued as rs144704487; called by muse, mutect2, varscan2
- TEX55 | c.542G>A p.R181K | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV55210968, COSV99817895; called by muse, mutect2, varscan2
- TF | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV53919996; called by muse, mutect2, varscan2
- TGFBR3 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV53024973; called by muse, mutect2, varscan2
- THSD7B | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV55681499; called by muse, mutect2, varscan2
- TLR10 | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as rs756647132, COSV58300201; called by muse, mutect2, varscan2
- TMEM41B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55155058; called by muse, mutect2
- TNFRSF17 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV50000677; called by muse, mutect2, varscan2
- TNFSF10 | c.419-1G>A p.X140_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as rs867854817, COSV99577665; called by muse, mutect2
- TOR4A | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1247790406, COSV62626899; called by muse, mutect2
- TRIM31 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV65059708; called by muse, mutect2
- TRRAP | c.7961C>T p.P2654L (on ENST00000359863 / NM_001244580.1; = p.P2636L on NM_003496.3) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV62843584; called by muse, mutect2, varscan2
- TTLL1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV56738547, COSV56738606; called by muse, mutect2, varscan2
- TTN | c.52169G>A p.G17390E (on ENST00000591111; = p.G9966E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | PolyPhen probably damaging (0.976); catalogued as rs1064797275, COSV60022755; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.35096C>T p.P11699L (on ENST00000591111; = p.P10772L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | PolyPhen benign (0.05); catalogued as COSV60022791; called by muse, mutect2, varscan2
- TTN | c.23474C>T p.P7825L (on ENST00000591111; = p.P6898L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | PolyPhen benign (0.003); catalogued as COSV59884618; called by muse, mutect2, varscan2
- TTN | c.5462G>A p.R1821K (on ENST00000591111; = p.R1775K on NM_003319.4) | Missense Mutation (SNP) | VAF 34/205 reads (17%) | PolyPhen probably damaging (0.987); catalogued as COSV60022820; called by muse, mutect2, varscan2
- TTN | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 29/171 reads (17%) | PolyPhen possibly damaging (0.839); catalogued as COSV60022869; called by muse, mutect2, varscan2
- TULP4 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65574934; called by muse, mutect2, varscan2
- TULP4 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs746537100, COSV65572777, COSV65574343; called by muse, mutect2, varscan2
- UNC13C | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52868202; called by muse, mutect2, varscan2
- USH2A | c.7883C>T p.P2628L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as CD095927, COSV100233043, COSV56397392; called by muse, mutect2, varscan2
- USH2A | c.7882C>T p.P2628S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs1452949901, COSV100232583, COSV56460347; called by muse, mutect2, varscan2
- USP26 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV63708647; called by muse, mutect2, varscan2
- VOPP1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53386729; called by muse, mutect2
- WT1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV60069621; called by muse, mutect2, varscan2
- ZNF395 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100733936; called by muse, mutect2, varscan2
- ZNF711 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1199153672, COSV52153693; called by muse, mutect2
- ZNF711 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV52153715; called by muse, mutect2, varscan2
- ZNF721 | c.1006C>T p.L336F (on ENST00000338977; = p.L348F on NM_133474.4) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1553863645, COSV59091924; called by muse, mutect2, varscan2
- ZNF778 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571194912, COSV60601284; called by muse, mutect2, varscan2
- ZNFX1 | c.4598G>A p.R1533Q | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100872317; called by muse, mutect2, varscan2
- ZP3 | c.259G>A p.E87K (on ENST00000394857 / NM_001110354.2; = p.E36K on NM_007155.6) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs777051289, COSV60630310, COSV60632646; called by muse, mutect2, varscan2
- ARHGAP39 | c.2421_2430delinsTG p.M808Vfs*28 | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by pindel, varscan2*
- ATP8B2 | c.1966G>T p.D656Y (on ENST00000672630; = p.D623Y on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); called by muse, mutect2
- FAM83C | c.1216_1220del p.P406Wfs*4 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- FCGBP | c.8054dup p.L2685Ffs*7 | Frame Shift Ins (INS) | VAF 22/178 reads (12%) | called by mutect2, varscan2
- GAS2L2 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEURL3 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TRAV38-1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.87); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ABCA13 | c.13386C>T p.I4462= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs375202986, COSV68944313; called by muse, mutect2
- ABCB10 | c.1899C>T p.L633= | Silent (SNP) | VAF 96/362 reads (27%) | catalogued as COSV60620949; called by muse, mutect2, varscan2
- ABCC8 | c.765C>T p.I255= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs753335564, COSV56849772; called by muse, mutect2, varscan2
- ABCF1 | c.2076C>T p.F692= (on ENST00000326195 / NM_001025091.2; = p.F654= on NM_001090.3) | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as COSV58227675, COSV58228922; called by muse, mutect2, varscan2
- ABLIM3 | c.1863C>T p.Y621= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV58642861; called by muse, mutect2, varscan2
- ABRA | c.663C>T p.P221= | Silent (SNP) | VAF 60/296 reads (20%) | catalogued as rs369741062, COSV61732323; called by muse, mutect2, varscan2
- ADAMTS18 | c.3300G>A p.K1100= | Silent (SNP) | VAF 31/255 reads (12%) | catalogued as COSV51398577, COSV51407276; called by muse, mutect2, varscan2
- ALAS1 | c.867C>T p.F289= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100050286; called by muse, mutect2, varscan2
- AMER2 | c.1311G>A p.Q437= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV63437256; called by muse, mutect2, varscan2
- ARHGEF17 | c.2970C>T p.F990= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs759365646, COSV55232152; called by muse, mutect2, varscan2
- ASPSCR1 | c.1233G>A p.E411= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs760430230, COSV100144855, COSV60728507; called by muse, mutect2, varscan2
- ASTN1 | c.1402C>T p.L468= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1445064804, COSV56067918; called by muse, mutect2, varscan2
- ATP13A1 | c.3096C>T p.S1032= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV52285295; called by muse, mutect2, varscan2
- ATP1A1 | c.672C>T p.P224= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as rs1476704974, COSV55191041; called by muse, mutect2, varscan2
- BCOR | c.780C>T p.S260= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1430817668; ClinVar: benign / likely benign; called by muse, mutect2
- BRCA2 | c.6216C>T p.S2072= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as rs786201410, COSV101204674, COSV66452994; ClinVar: likely benign; called by muse, mutect2, varscan2
- C1QC | c.255G>A p.G85= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV65889228; called by muse, mutect2, varscan2
- CACNA1C | c.1185C>T p.F395= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs1455190942, COSV59713206; called by muse, mutect2
- CADPS | c.1254C>T p.I418= | Silent (SNP) | VAF 86/202 reads (43%) | catalogued as rs1434547440, COSV51877820; called by muse, mutect2, varscan2
- CATSPERB | c.2814G>A p.R938= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV56437203; called by muse, mutect2, varscan2
- CCDC191 | c.2526C>T p.F842= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV55671882; called by muse, mutect2, varscan2
- CCDC60 | c.1431G>A p.V477= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV59543297; called by muse, mutect2, varscan2
- CDK18 | c.909C>T p.I303= (on ENST00000506784 / NM_212503.3; = p.I273= on NM_002596.4) | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as COSV63727336; called by muse, mutect2, varscan2
- CEP85 | c.1950G>A p.Q650= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV53329083; called by muse, mutect2, varscan2
- CFAP221 | c.1050A>G p.S350= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV54656914; called by muse, mutect2, varscan2
- COL6A2 | c.1605C>T p.P535= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs377476546; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- CORIN | c.705G>A p.P235= | Silent (SNP) | VAF 26/225 reads (12%) | catalogued as rs755107174, COSV56690711; called by muse, mutect2, varscan2
- CRB1 | c.2373A>T p.G791= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV66329894; called by muse, mutect2, varscan2
- CREB3L3 | c.1110C>T p.R370= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs1404287349, COSV50172800; called by muse, mutect2, varscan2
- CST8 | c.63G>A p.R21= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as COSV55671024; called by muse, mutect2, varscan2
- DLGAP1 | c.1176C>T p.I392= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV59800866; called by muse, mutect2, varscan2
- DNMT3A | c.726C>T p.A242= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99261693; called by muse, mutect2, varscan2
- ECRG4 | c.396G>A p.R132= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV53000758; called by muse, mutect2, varscan2
- EIF2B1 | c.240C>T p.S80= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV57458728; called by muse, mutect2, varscan2
- ELFN2 | c.1617G>A p.K539= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV104433829, COSV68744449; called by muse, mutect2, varscan2
- ELP1 | c.87A>G p.E29= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV59829150; called by muse, mutect2, varscan2
- ENPP6 | c.933G>A p.K311= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV57067319, COSV57067697; called by muse, mutect2, varscan2
- EPHA5 | c.1539C>T p.T513= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV56642975; called by muse, mutect2, varscan2
- EPHA6 | c.1233C>T p.F411= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV67570526; called by muse, mutect2, varscan2
- EPHB2 | c.1290C>T p.T430= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV65862255; called by muse, mutect2
- FAM71F1 | c.264G>A p.R88= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV59373487; called by muse, mutect2, varscan2
- FGF4 | c.570G>A p.G190= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV51449900; called by muse, mutect2, varscan2
- FUBP1 | c.531C>T p.F177= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as COSV53930246; called by muse, mutect2, varscan2
- GAS2L2 | c.2184G>A p.S728= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as rs782511543; called by muse, mutect2, varscan2
- GRN | c.1578C>T p.F526= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV50006983; called by muse, mutect2, varscan2
- GTSF1L | c.90G>A p.R30= | Silent (SNP) | VAF 32/237 reads (14%) | catalogued as rs1355218304, COSV65932434; called by muse, mutect2, varscan2
- HHLA2 | c.306G>A p.G102= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV63317001; called by muse, mutect2, varscan2
- IKZF1 | c.978C>T p.S326= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV58785229; called by muse, mutect2, varscan2
- ITGA9 | c.2217C>T p.F739= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs763735003, COSV53241296; called by muse, mutect2, varscan2
- JAG2 | c.1842C>T p.S614= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs772353310, COSV59308644; called by muse, mutect2, varscan2
- KALRN | c.2946G>A p.E982= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV53761997; called by muse, mutect2, varscan2
- KCNH3 | c.438G>A p.K146= | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as COSV57790599; called by muse, mutect2
- KCNK1 | c.990G>A p.V330= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs1009466525, COSV64035027; called by muse, mutect2, varscan2
- KIRREL3 | c.1209C>T p.P403= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV101375170, COSV69384303; called by muse, mutect2, varscan2
- KLHL26 | c.1725G>A p.T575= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV56316639; called by muse, mutect2, varscan2
- KRT84 | c.288G>A p.G96= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV57771557; called by muse, mutect2, varscan2
- LOXL3 | c.2046G>A p.T682= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs375537672; called by muse, mutect2, varscan2
- LRRC7 | c.315C>T p.N105= (on ENST00000651989 / NM_001370785.2; = p.N72= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV50449784; called by muse, mutect2, varscan2
- MAP3K5 | c.3171C>T p.I1057= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as rs368851337, COSV62892463; called by muse, mutect2
- MARCO | c.279C>T p.S93= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs767108104, COSV100503906, COSV59054014; called by muse, mutect2, varscan2
- MDFI | c.327G>A p.E109= | Silent (SNP) | VAF 49/272 reads (18%) | catalogued as COSV57821974; called by muse, mutect2, varscan2
- MDH1B | c.1188G>A p.E396= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV65589499; called by muse, mutect2, varscan2
- MROH9 | c.838C>T p.L280= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs767663627, COSV63011080, COSV63012065; called by muse, mutect2, varscan2
- MUC16 | c.35031G>A p.R11677= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV67462716; called by muse, mutect2, varscan2
- MYO10 | c.2673C>T p.L891= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV57020733; called by muse, mutect2, varscan2
- MYOC | c.1008C>T p.F336= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as CM095398, COSV50676405, COSV50679717, COSV99231441; called by muse, mutect2, varscan2
- NAT2 | c.246C>T p.I82= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as rs751374116, COSV54061906; called by muse, mutect2, varscan2
- NBAS | c.2662C>T p.L888= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV55720112; called by muse, mutect2, varscan2
- NLRP6 | c.2440C>T p.L814= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV56459466; called by muse, mutect2, varscan2
- NOTCH1 | c.1203C>T p.P401= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV53047891; called by muse, mutect2, varscan2
- NRXN2 | c.982C>T p.L328= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as COSV55452287; called by muse, mutect2
- NUTM2F | c.1435T>C p.L479= | Silent (SNP) | VAF 73/282 reads (26%) | catalogued as COSV53556967; called by muse, mutect2, varscan2
- NXPE3 | c.1383G>A p.R461= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV56289516; called by muse, mutect2, varscan2
- OR10A6 | c.144C>T p.I48= | Silent (SNP) | VAF 32/186 reads (17%) | catalogued as rs748785836, COSV59165009, COSV59165908; called by muse, mutect2, varscan2
- OR11H6 | c.120G>A p.E40= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV59644139; called by muse, mutect2, varscan2
- OR13F1 | c.420C>T p.T140= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as rs944735273, COSV58251461; called by muse, mutect2, varscan2
- OR13H1 | c.903G>A p.R301= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV58547563; called by muse, mutect2, varscan2
- OR51T1 | c.780C>T p.L260= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs111347642, COSV59025144; called by muse, mutect2, varscan2
- OR52H1 | c.741C>T p.V247= (on ENST00000322653; = p.V253= on NM_001005289.1) | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV59505292, COSV59505309, COSV59505935; called by muse, mutect2, varscan2
- OR5H2 | c.417G>A p.V139= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV62350649; called by muse, mutect2, varscan2
- OR5I1 | c.267G>A p.S89= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs763571238, COSV100041363; called by muse, mutect2, varscan2
- OR8D1 | c.57G>A p.Q19= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as COSV63442144; called by muse, mutect2, varscan2
- OR9I1 | c.912C>T p.V304= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as rs368868026, COSV56925654, COSV56925909; called by muse, mutect2, varscan2
- PADI4 | c.237G>A p.T79= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs750711340, COSV64922926; called by muse, mutect2, varscan2
- PAIP2B | c.81G>A p.K27= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV54908851; called by muse, mutect2, varscan2
- PBXIP1 | c.1452C>T p.D484= | Silent (SNP) | VAF 72/441 reads (16%) | catalogued as COSV100870064; called by muse, mutect2, varscan2
- PCDHB1 | c.714C>T p.H238= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV60630646; called by muse, mutect2, varscan2
- PDE4A | c.1827C>T p.I609= (on ENST00000380702 / NM_001111307.2; = p.I370= on NM_006202.3) | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs993050875, COSV53354737; called by muse, mutect2, varscan2
- PLA2G4D | c.570G>A p.K190= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV51820521; called by muse, mutect2, varscan2
- PLAA | c.801C>T p.I267= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV101263508; called by muse, mutect2, varscan2
- PLCB4 | c.3270C>T p.A1090= | Silent (SNP) | VAF 27/181 reads (15%) | catalogued as COSV53800352; called by muse, mutect2, varscan2
- PLCL1 | c.1887G>A p.E629= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV70829169; called by muse, mutect2, varscan2
- PLXNA4 | c.4575C>T p.I1525= | Silent (SNP) | VAF 133/420 reads (32%) | catalogued as rs1393582207, COSV58122154; called by muse, mutect2, varscan2
- PPM1E | c.1368G>A p.E456= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1240402723, COSV57573601; called by muse, mutect2, varscan2
- PROX2 | c.1524A>G p.T508= (on ENST00000556489 / NM_001243007.1; = p.T281= on NM_001080408.2) | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as COSV71520039; called by muse, mutect2, varscan2
- PTPRT | c.2967G>A p.L989= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs780821966, COSV61978451; called by muse, mutect2, varscan2
- RICTOR | c.3192C>T p.I1064= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as COSV57121310; called by muse, mutect2, varscan2
- SCARF1 | c.2070G>A p.T690= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs773796651, COSV53958514; called by muse, mutect2, varscan2
- SLC12A3 | c.669C>T p.F223= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs779986569, COSV52633150; called by muse, mutect2, varscan2
- SLC25A31 | c.597C>T p.Y199= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV55419024; called by muse, mutect2
- SLCO5A1 | c.1395C>T p.I465= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV52656807; called by muse, mutect2, varscan2
- SMARCA5 | c.429C>T p.H143= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV51644020; called by muse, mutect2, varscan2
- SPEN | c.8805G>T p.G2935= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV65361252; called by muse, mutect2, varscan2
- SPHKAP | c.732G>A p.L244= | Silent (SNP) | VAF 65/196 reads (33%) | catalogued as COSV60877195; called by muse, mutect2, varscan2
- SRP9 | c.180G>A p.K60= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV59159071; called by muse, mutect2
- STEAP3 | c.1083C>T p.L361= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs961829995, COSV100713268; called by muse, mutect2, varscan2
- STRA6 | c.1224G>A p.R408= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV60585975; called by muse, mutect2, varscan2
- STXBP5L | c.291C>T p.L97= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs779254023, COSV56511737; called by muse, mutect2, varscan2
- SULT1C3 | c.276G>A p.L92= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV61252868; called by muse, mutect2, varscan2
- TAS1R1 | c.885G>A p.K295= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV59839728; called by muse, mutect2, varscan2
- THBS1 | c.663C>T p.T221= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as COSV52951639; called by muse, mutect2, varscan2
- TIAM2 | c.3852G>A p.E1284= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV51639965; called by muse, mutect2, varscan2
- TMEM74 | c.873G>A p.L291= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV52463136; called by muse, mutect2, varscan2
- TNFSF8 | c.504C>T p.I168= | Silent (SNP) | VAF 36/218 reads (17%) | catalogued as COSV56342428; called by muse, mutect2, varscan2
- TRANK1 | c.4047C>T p.S1349= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV57148783; called by muse, mutect2, varscan2
- TRIM11 | c.1146C>T p.F382= | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as rs1338898122, COSV52857636; called by muse, mutect2, varscan2
- TRRAP | c.6447C>T p.F2149= (on ENST00000359863 / NM_001244580.1; = p.F2131= on NM_003496.3) | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs779209083, COSV62843571; called by muse, mutect2, varscan2
- TSHZ2 | c.2847G>T p.L949= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV61588509; called by muse, mutect2, varscan2
- TTN | c.71331C>T p.T23777= (on ENST00000591111; = p.T16353= on NM_003319.4) | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs1168341983, COSV60022724; called by muse, mutect2, varscan2
- USP6NL | c.1554C>T p.T518= | Silent (SNP) | VAF 58/238 reads (24%) | catalogued as rs367788287, COSV53209832, COSV53210987; called by muse, mutect2, varscan2
- WNK1 | c.1173C>T p.A391= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as rs1366102202, COSV60032114; called by muse, mutect2, varscan2
- XYLB | c.486C>A p.L162= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV52912848; called by muse, mutect2
- YEATS2 | c.1881C>T p.S627= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV59364962, COSV59366169; called by muse, mutect2, varscan2
- ZBTB49 | c.1662C>T p.V554= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV61924943; called by muse, mutect2, varscan2
- ZNF200 | c.492T>G p.G164= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV67723777; called by muse, mutect2, varscan2
- ZNF202 | c.1023T>G p.P341= | Silent (SNP) | VAF 50/275 reads (18%) | catalogued as COSV60246986; called by muse, mutect2, varscan2
- ZNF343 | c.1698C>T p.V566= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV53853587; called by muse, mutect2, varscan2
- ZNFX1 | c.4599A>C p.R1533= | Silent (SNP) | VAF 41/276 reads (15%) | catalogued as COSV100872316; called by muse, mutect2, varscan2
- ZSWIM5 | c.2466C>T p.L822= | Silent (SNP) | VAF 50/271 reads (18%) | catalogued as COSV62734050; called by muse, mutect2, varscan2
- ABCC9 | chr12:21801129 C>T | 3'Flank (SNP) | VAF 10/99 reads (10%) | catalogued as COSV53963793, COSV99684550; called by muse, mutect2, varscan2
- ANK3 | c.12596-284G>T | Intron (SNP) | VAF 27/165 reads (16%) | catalogued as COSV55065943, COSV99779488; called by muse, mutect2, varscan2
- ANK3 | c.12596-285T>G | Intron (SNP) | VAF 27/165 reads (16%) | catalogued as COSV99779492; called by muse, mutect2, varscan2
- FMN1 | c.2044-1574C>T | Intron (SNP) | VAF 19/114 reads (17%) | catalogued as rs752787150, COSV57921299; called by muse, mutect2, varscan2
- MIR18A | n.66C>T | RNA (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- OR2W5 | n.1120G>A | RNA (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- PRMT8 | c.76-1944G>A | Intron (SNP) | VAF 15/124 reads (12%) | catalogued as rs370062295; called by muse, mutect2, varscan2
- RNASET2 | c.446+314T>G | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- STK4 | c.1306-21898T>C | Intron (SNP) | VAF 41/119 reads (34%) | catalogued as COSV100860037; called by muse, mutect2, varscan2
- TAOK2 | chr16:29991090 G>A | 3'Flank (SNP) | VAF 12/83 reads (14%) | catalogued as rs1285651838, COSV54229799; called by muse, mutect2, varscan2
